Somatic mutation profile of tumor specimen C3L-08238-01 (aliquot CPT0485160007) from CPTAC case C3L-08238, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 46.7 years (17,053 days).
Specimen C3L-08238-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ecabec2-d8f7-43e3-a47d-9f8cc01deea4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08238-32 (Blood Derived Normal), aliquot CPT0485310003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17d6397c-34d6-41ca-ac49-1a4338110229

The open-access MAF lists 173 somatic variants for this specimen: 125 protein-altering or splice-affecting, 41 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 41, Intron 3, Nonsense Mutation 3, 5'Flank 2, Frame Shift Del 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD11 | c.3008A>C p.K1003T (on ENST00000280758 / NM_001018072.2; = p.K540T on NM_001017523.2) | Missense Mutation (SNP) | VAF 14/291 reads (5%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen probably damaging (0.946); catalogued as COSV55025836, COSV55028973, COSV55038748; called by muse, mutect2
- CDH1 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 42/479 reads (9%) | catalogued as rs121964877, CM980318, COSV55731120, COSV55734398; ClinVar: pathogenic; called by muse, mutect2
- ERBB3 | c.850G>C p.G284R | Missense Mutation (SNP) | VAF 24/422 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV57246350, COSV57249681; called by muse, mutect2
- GAA | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs543300039, CM980801, COSV100163190; ClinVar: pathogenic; called by muse, mutect2
- MAP2K1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 24/324 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1057519733, CM083720, COSV61068654; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 41/311 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.14794G>A p.G4932S | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199630323, COSV101291324; called by muse, mutect2
- ABCC8 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs750817645; called by muse, mutect2
- ABCC9 | c.2118A>C p.Q706H | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV99685426; called by muse, mutect2
- ADAMTS20 | c.1780T>G p.Y594D | Missense Mutation (SNP) | VAF 18/447 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101239059; called by muse, mutect2
- ANK1 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 29/380 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as rs140138043; called by muse, mutect2
- ANKRD54 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 25/440 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as rs1343169499; called by muse, mutect2
- ASCL4 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 17/422 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs998137429; called by muse, mutect2
- ASTN1 | c.2075T>G p.L692R | Missense Mutation (SNP) | VAF 32/333 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99920060; called by muse, mutect2
- BHLHE22 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 25/514 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58861275; called by muse, mutect2
- CDS2 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 24/479 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as COSV66897016; called by muse, mutect2
- CGB1 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 53/654 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.988); catalogued as rs572197136; called by muse, mutect2
- CHRD | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV52606446; called by muse, mutect2
- CHST15 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 55/399 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs750910183, COSV60562428; called by muse, mutect2, varscan2
- CLDN23 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 32/597 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1452231517, COSV67731530; called by muse, mutect2
- CLEC2B | c.439A>G p.R147G | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs914310982; called by muse, mutect2
- CMIP | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 32/339 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV101606979; called by muse, mutect2
- CNNM1 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 28/501 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs772053824, COSV63202072; called by muse, mutect2
- CNTNAP5 | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101444401, COSV70498945; called by muse, mutect2, varscan2
- CTNNB1 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 23/345 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV100846271; called by muse, mutect2
- DLL3 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 48/432 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs1354064251; called by muse, mutect2, varscan2
- DNAH9 | c.3893A>C p.E1298A | Missense Mutation (SNP) | VAF 21/521 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV99308358; called by muse, mutect2
- DPYSL3 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 25/422 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs749696414; called by muse, mutect2
- EIF2AK1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 33/395 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as rs1329655438; called by muse, mutect2
- EPHA4 | c.1937G>C p.R646T | Missense Mutation (SNP) | VAF 56/465 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99917443; called by muse, mutect2, varscan2
- FSIP2 | c.8209A>C p.I2737L | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100554568; called by muse, mutect2
- GALNT17 | c.871T>G p.S291A | Missense Mutation (SNP) | VAF 39/576 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV100354141; called by muse, mutect2
- GMNC | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 34/492 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1173471446; called by muse, mutect2
- GNRHR | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 30/502 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325732095, CM066865, COSV56933216, COSV56933808; called by muse, mutect2
- LAMA1 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67543584; called by muse, mutect2
- LILRA2 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 72/852 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs764683666, COSV99253321; called by muse, mutect2
- MAP1A | c.6293G>A p.R2098Q | Missense Mutation (SNP) | VAF 41/568 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs772974141; called by muse, mutect2
- MARK2 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 19/478 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59283996, COSV59285604; called by muse, mutect2
- MYH3 | c.3449G>A p.R1150Q | Missense Mutation (SNP) | VAF 48/529 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs752339755; ClinVar: likely benign; called by muse, mutect2
- MYH7B | c.4219C>T p.R1407W | Missense Mutation (SNP) | VAF 72/710 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs746131334, COSV99328451; called by muse, mutect2
- MYO18B | c.7153C>T p.R2385W | Missense Mutation (SNP) | VAF 56/489 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs767625703, COSV59128196; called by muse, mutect2, varscan2
- NBEA | c.468A>C p.E156D | Missense Mutation (SNP) | VAF 42/530 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV100076744; called by muse, mutect2
- NRG1 | c.1594G>A p.E532K (on ENST00000405005 / NM_013964.5; = p.E537K on NM_013956.5) | Missense Mutation (SNP) | VAF 46/548 reads (8%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.998); catalogued as rs371549708; called by muse, mutect2
- NUAK1 | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 51/551 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1458958342; called by muse, mutect2
- OR4C13 | c.455T>A p.L152H | Missense Mutation (SNP) | VAF 27/380 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV73648601; called by muse, mutect2
- OR5T1 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 38/578 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV57302939; called by muse, mutect2
- PACSIN3 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 35/488 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs771622095; called by muse, mutect2
- PCDH18 | c.2542A>C p.S848R | Missense Mutation (SNP) | VAF 32/477 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV100787028, COSV61271459; called by muse, mutect2
- PCDHA9 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.123); catalogued as rs782567110, COSV65323587; called by muse, mutect2, varscan2
- PCDHB3 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 27/267 reads (10%) | catalogued as COSV50566173, COSV50578116; called by muse, mutect2
- PEG3 | c.4236A>C p.E1412D | Missense Mutation (SNP) | VAF 62/710 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV55625532, COSV55636235; called by muse, mutect2
- PKD1L1 | c.4661G>A p.R1554K | Missense Mutation (SNP) | VAF 39/557 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV56964428; called by muse, mutect2
- PRAMEF6 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 37/560 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs756266940, COSV61910149; called by muse, mutect2
- PROX1 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 32/590 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); catalogued as rs753030931; called by muse, mutect2
- PTGDR | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 24/488 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs766336885; called by muse, mutect2
- RHOA | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 26/391 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV69042538; called by muse, mutect2
- ROS1 | c.2353G>A p.V785M | Missense Mutation (SNP) | VAF 45/524 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs763408803, COSV63861954; called by muse, mutect2
- SCN10A | c.4343A>C p.K1448T | Missense Mutation (SNP) | VAF 44/426 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV71860120; called by muse, mutect2
- SCN9A | c.941T>A p.L314H | Missense Mutation (SNP) | VAF 13/313 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100311848; called by muse, mutect2
- SLC1A7 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1264265912, COSV65198673; called by muse, mutect2
- SLC5A6 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 56/597 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs201078481, COSV60160687; called by muse, mutect2
- SLC7A9 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.527); catalogued as rs1282862614, COSV50090952; called by muse, mutect2
- SOX3 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); catalogued as COSV100983789; called by muse, mutect2, varscan2
- SVEP1 | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576679965; called by muse, mutect2, varscan2
- TBX18 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 39/492 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762412545, COSV63736567; called by muse, mutect2
- TLL1 | c.2097A>C p.E699D | Missense Mutation (SNP) | VAF 47/593 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.617); catalogued as rs1441976412; called by muse, mutect2
- TMEM132D | c.2594A>C p.K865T | Missense Mutation (SNP) | VAF 32/540 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV101242707, COSV67158649; called by muse, mutect2
- TNS1 | c.3382C>A p.Q1128K | Missense Mutation (SNP) | VAF 35/622 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV50708382; called by muse, mutect2
- TP53BP1 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 14/447 reads (3%) | catalogued as COSV55505002; called by muse, mutect2
- TRIM32 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 28/481 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs564290779, COSV100530717; called by muse, mutect2
- TRPV4 | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 45/474 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as rs149267166; called by muse, mutect2
- UNC13C | c.3945A>C p.E1315D | Missense Mutation (SNP) | VAF 21/464 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV52847570, COSV99524809; called by muse, mutect2
- VPS53 | c.1787C>T p.T596I (on ENST00000571805 / NM_001366253.2; = p.T567I on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs761805836; called by muse, mutect2
- WHRN | c.2269G>A p.G757R | Missense Mutation (SNP) | VAF 47/529 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377488287, COSV99470167; called by muse, mutect2
- ZNF300 | c.1766A>C p.K589T | Missense Mutation (SNP) | VAF 20/492 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV51032220; called by muse, mutect2
- ACADSB | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ALDOC | c.643A>G p.K215E | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- ALMS1 | c.4718T>A p.F1573Y | Missense Mutation (SNP) | VAF 60/618 reads (10%) | SIFT tolerated (0.95); PolyPhen benign (0.053); called by muse, mutect2
- ANKIB1 | c.2091A>T p.K697N | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2
- ANKRD34C | c.691T>G p.S231A | Missense Mutation (SNP) | VAF 29/462 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); called by muse, mutect2
- C10orf71 | c.1499T>A p.L500Q | Missense Mutation (SNP) | VAF 59/492 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNB2 | c.1059A>C p.E353D (on ENST00000324631 / NM_201596.3; = p.E298D on NM_000724.4) | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CDK8 | c.526T>G p.F176V | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2
- CHD4 | c.3484G>C p.V1162L (on ENST00000357008 / NM_001363606.2; = p.V1175L on NM_001273.5) | Missense Mutation (SNP) | VAF 14/445 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- CNGA2 | c.1618A>T p.I540F | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTN6 | c.2802A>C p.E934D | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- CRTAC1 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.391); called by muse, mutect2
- DMXL2 | c.6464T>A p.L2155Q | Missense Mutation (SNP) | VAF 28/554 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- EDNRB | c.322G>A p.A108T (on ENST00000377211 / NM_001201397.1; = p.A18T on NM_000115.5) | Missense Mutation (SNP) | VAF 66/511 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- EYA1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- FAM135B | c.2617G>C p.V873L | Missense Mutation (SNP) | VAF 21/651 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- FBLL1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.11); called by muse, mutect2, varscan2
- FBXL19 | c.1506G>T p.W502C | Missense Mutation (SNP) | VAF 21/412 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2
- FGF5 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 15/438 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2
- FSIP2 | c.3416T>G p.V1139G | Missense Mutation (SNP) | VAF 29/482 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2
- FZD9 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 47/523 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by muse, mutect2
- IL4I1 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 24/490 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2
- LRRTM4 | c.500A>C p.N167T | Missense Mutation (SNP) | VAF 39/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LYST | c.4467T>A p.S1489R | Missense Mutation (SNP) | VAF 33/409 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- MN1 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 44/589 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MUC16 | c.12401A>T p.K4134M | Missense Mutation (SNP) | VAF 22/502 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); called by muse, mutect2
- NKX2-5 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 23/592 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR14A2 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 18/455 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- OR2I1P | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 42/471 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- POU4F2 | c.1001T>A p.L334H | Missense Mutation (SNP) | VAF 16/580 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); called by muse, mutect2
- QRFPR | c.14A>C p.N5T | Missense Mutation (SNP) | VAF 10/308 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- RPS28 | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 46/514 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.166); called by muse, mutect2
- SMARCA2 | c.3478G>A p.A1160T | Missense Mutation (SNP) | VAF 25/313 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SMARCAD1 | c.2591del p.S864Lfs*3 | Frame Shift Del (DEL) | VAF 22/237 reads (9%) | called by mutect2, pindel
- SNTG2 | c.817T>A p.S273T | Missense Mutation (SNP) | VAF 39/549 reads (7%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.985); called by muse, mutect2
- SPEF2 | c.2525A>G p.D842G | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- SRSF1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 19/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM233 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 23/315 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2
- TRBV7-1 | c.133A>C p.I45L | Missense Mutation (SNP) | VAF 33/431 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); called by muse, mutect2
- TRIM43B | c.643A>C p.S215R | Missense Mutation (SNP) | VAF 39/537 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.38); called by muse, mutect2
- TRPS1 | c.1064T>G p.L355R (on ENST00000220888 / NM_001330599.2; = p.L368R on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/550 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- TTN | c.34201A>C p.K11401Q (on ENST00000591111; = p.K10474Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/378 reads (10%) | PolyPhen benign (0.046); called by muse, mutect2
- TULP3 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 34/441 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2
- UNC5D | c.1783T>C p.S595P | Missense Mutation (SNP) | VAF 13/321 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- VAT1L | c.311T>G p.F104C | Missense Mutation (SNP) | VAF 33/366 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- WDFY4 | c.3214T>G p.F1072V | Missense Mutation (SNP) | VAF 32/554 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); called by muse, mutect2
- WDR35 | c.2638T>A p.L880M (on ENST00000345530 / NM_001006657.2; = p.L869M on NM_020779.4) | Missense Mutation (SNP) | VAF 22/469 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.362); called by muse, mutect2
- ZCCHC24 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 51/291 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF568 | c.594del p.K199Rfs*63 | Frame Shift Del (DEL) | VAF 34/344 reads (10%) | called by mutect2, pindel
- ZP1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- AC099489.1 | c.7716C>T p.R2572= | Silent (SNP) | VAF 30/455 reads (7%) | called by muse, mutect2
- CACNA1C | c.6468C>T p.G2156= (on ENST00000399634 / NM_001167625.1; = p.G2085= on NM_000719.7) | Silent (SNP) | VAF 51/619 reads (8%) | catalogued as COSV59750393; called by muse, mutect2
- CACNA1E | c.2013T>G p.G671= | Silent (SNP) | VAF 18/484 reads (4%) | called by muse, mutect2
- CGGBP1 | c.378C>T p.V126= | Silent (SNP) | VAF 30/529 reads (6%) | called by muse, mutect2
- CHRNA7 | c.1203C>T p.P401= | Silent (SNP) | VAF 42/968 reads (4%) | catalogued as rs1315462777; called by muse, mutect2
- CMTM1 | c.468C>T p.A156= (on ENST00000457188 / NM_181269.3; = p.A273= on NM_052999.4) | Silent (SNP) | VAF 40/522 reads (8%) | called by muse, mutect2
- CNTN1 | c.1242T>G p.T414= | Silent (SNP) | VAF 24/336 reads (7%) | called by muse, mutect2
- CNTNAP4 | c.2835A>G p.E945= | Silent (SNP) | VAF 16/448 reads (4%) | catalogued as COSV56666630; called by muse, mutect2
- COL4A5 | c.126C>A p.G42= | Silent (SNP) | VAF 27/185 reads (15%) | called by muse, mutect2, varscan2
- CSMD3 | c.10767T>G p.T3589= (on ENST00000297405 / NM_001363185.1; = p.T3420= on NM_052900.3) | Silent (SNP) | VAF 24/392 reads (6%) | catalogued as COSV52094260; called by muse, mutect2
- FAM160B2 | c.165G>A p.R55= | Silent (SNP) | VAF 52/404 reads (13%) | called by muse, mutect2, varscan2
- HELZ2 | c.3276C>T p.D1092= (on ENST00000467148 / NM_001037335.2; = p.D523= on NM_033405.3) | Silent (SNP) | VAF 46/482 reads (10%) | catalogued as rs368505725; called by muse, mutect2
- JAKMIP1 | c.1359G>A p.T453= | Silent (SNP) | VAF 29/462 reads (6%) | catalogued as rs769869746, COSV51527872; called by muse, mutect2
- KCNH5 | c.252T>G p.T84= | Silent (SNP) | VAF 26/406 reads (6%) | catalogued as rs1223162084, COSV59756116, COSV59779615; called by muse, mutect2
- LRRC6 | c.1017T>G p.T339= | Silent (SNP) | VAF 34/479 reads (7%) | called by muse, mutect2
- MAP3K20 | c.1191C>A p.I397= | Silent (SNP) | VAF 18/394 reads (5%) | called by muse, mutect2
- MNX1 | c.747C>T p.T249= | Silent (SNP) | VAF 20/438 reads (5%) | called by muse, mutect2
- NOTUM | c.120G>A p.E40= | Silent (SNP) | VAF 18/592 reads (3%) | called by muse, mutect2
- NPTX2 | c.81C>T p.F27= | Silent (SNP) | VAF 42/554 reads (8%) | called by muse, mutect2
- OR10J4 | c.321T>G p.T107= | Silent (SNP) | VAF 43/484 reads (9%) | called by muse, mutect2
- OR2M5 | c.546T>C p.P182= | Silent (SNP) | VAF 48/444 reads (11%) | catalogued as rs758076955; called by muse, mutect2, varscan2
- OR4A15 | c.822T>G p.T274= | Silent (SNP) | VAF 45/488 reads (9%) | catalogued as COSV59035832; called by muse, mutect2
- POU4F2 | c.618G>A p.A206= | Silent (SNP) | VAF 37/681 reads (5%) | catalogued as rs202030431; called by muse, mutect2
- PTPN14 | c.2259C>T p.P753= | Silent (SNP) | VAF 31/670 reads (5%) | catalogued as rs548947717, COSV100872972; called by muse, mutect2
- PURG | c.525T>C p.Y175= | Silent (SNP) | VAF 14/474 reads (3%) | called by muse, mutect2
- RFC2 | c.522G>A p.S174= (on ENST00000055077 / NM_181471.3; = p.S140= on NM_002914.4) | Silent (SNP) | VAF 26/362 reads (7%) | catalogued as rs139127548; called by muse, mutect2
- RHBDF1 | c.1143C>T p.N381= | Silent (SNP) | VAF 48/662 reads (7%) | catalogued as COSV51954632; called by muse, mutect2
- RIMS1 | c.2856T>G p.R952= | Silent (SNP) | VAF 21/475 reads (4%) | called by muse, mutect2
- RIMS2 | c.3378T>G p.P1126= | Silent (SNP) | VAF 24/441 reads (5%) | called by muse, mutect2
- SCG3 | c.426C>T p.D142= | Silent (SNP) | VAF 36/442 reads (8%) | catalogued as rs144732016; called by muse, mutect2
- SLC35E4 | c.816C>T p.S272= | Silent (SNP) | VAF 59/540 reads (11%) | called by muse, mutect2, varscan2
- SMYD2 | c.540C>T p.N180= | Silent (SNP) | VAF 38/356 reads (11%) | called by muse, mutect2, varscan2
- SPTAN1 | c.1350G>A p.A450= | Silent (SNP) | VAF 32/469 reads (7%) | catalogued as rs374478564, COSV100824119; ClinVar: likely benign; called by muse, mutect2
- STRA6 | c.1014C>T p.A338= | Silent (SNP) | VAF 50/624 reads (8%) | catalogued as rs1345912861, COSV60588191; called by muse, mutect2
- TECRL | c.558T>G p.A186= | Silent (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- TLR4 | c.735T>G p.T245= (on ENST00000355622 / NM_138554.5; = p.T205= on NM_003266.4) | Silent (SNP) | VAF 20/350 reads (6%) | called by muse, mutect2
- TSPYL2 | c.1278C>T p.D426= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as rs186095471, COSV100966261; called by muse, mutect2
- XIRP1 | c.3894T>C p.P1298= | Silent (SNP) | VAF 48/557 reads (9%) | called by muse, mutect2
- ZCCHC2 | c.2940C>T p.T980= | Silent (SNP) | VAF 44/601 reads (7%) | catalogued as rs533096174, COSV99502588; called by muse, mutect2
- ZNF254 | c.367A>C p.R123= | Silent (SNP) | VAF 23/269 reads (9%) | called by muse, mutect2
- ZNF90 | c.496A>C p.R166= | Silent (SNP) | VAF 17/324 reads (5%) | called by muse, mutect2
- C2orf16 | chr2:27571994 G>C | 5'Flank (SNP) | VAF 20/314 reads (6%) | called by muse, mutect2
- CBX2 | c.288+130G>A | Intron (SNP) | VAF 44/600 reads (7%) | catalogued as rs377211900; called by muse, mutect2
- CHCHD5 | c.309+84G>A | Intron (SNP) | VAF 52/626 reads (8%) | catalogued as rs1318625540; called by muse, mutect2
- OR11H6 | chr14:20229545 A>C | 3'Flank (SNP) | VAF 46/390 reads (12%) | called by muse, mutect2, varscan2
- PLEKHG4B | chr5:139724 C>T | 5'Flank (SNP) | VAF 35/409 reads (9%) | catalogued as rs1286908976; called by muse, mutect2
- RAB20 | c.*272G>A | 3'UTR (SNP) | VAF 54/602 reads (9%) | catalogued as rs991007090; called by muse, mutect2
- TRRAP | c.9860-37C>T | Intron (SNP) | VAF 38/644 reads (6%) | catalogued as rs1490922743, COSV62854023; called by muse, mutect2
